Gene-level copy-number profile of tumor specimen TCGA-20-0991-01A from TCGA case TCGA-20-0991, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 78.6 years (28,694 days).
Specimen TCGA-20-0991-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.05fd7ce0-b787-48fa-baa6-3bfe9647f4ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-0991-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/64e4da57-762c-4f90-835a-ac141eb12f90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,739; copy number 2: 10,899; copy number 3: 20,604; copy number 4: 16,630; copy number 5: 3,419; copy number 6: 3,551; copy number 7: 1,293; copy number 8: 512; copy number 9: 493; copy number 11: 70; copy number 12: 324; copy number 13: 57; copy number 14: 50; copy number 15: 69; copy number 16: 36; copy number 18: 29; copy number 19: 5; copy number 20: 6; copy number 21: 19; copy number 22: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-0991-01A-03D-0428-01): tumor purity 0.53, ploidy 3.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,964 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:34,850,694–40,133,448, 159 genes, copy number 7–22 (broad region; genes not listed).
- chr1:40,344,850–44,725,591, 148 genes, copy number 11–21 (broad region; genes not listed).
- chr1:44,850,522–46,316,776, 48 genes, copy number 9–11 (within-gene range 6–11): EIF2B3, RNA5SP47, CCNB1IP1P1, PPIAP35, MRPS17P1, HECTD3, UROD, ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2, PIK3R3, P3R3URF-PIK3R3, AL358075.1, AL358075.3, AL358075.2, TSPAN1, P3R3URF, POMGNT1, LURAP1, RAD54L, LRRC41, UQCRH.
- chr1:102,763,322–110,631,474, 137 genes, copy number 7–18 (broad region; genes not listed).
- chr1:113,812,379–118,264,489, 101 genes, copy number 7–20 (broad region; genes not listed).
- chr1:237,042,184–240,776,824, 51 genes, copy number 7 (within-gene range 6–7): RYR2, RN7SKP195, MIR4428, AL442065.1, AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8.
- chr1:240,823,006–240,823,433, 1 gene, copy number 7: RFKP1.
- chr5:57,422,464–57,424,391, 1 gene, copy number 7: SALL4P1.
- chr6:33,999,972–39,314,461, 136 genes, copy number 7–13 (within-gene range 6–13) (broad region; genes not listed).
- chr6:41,546,426–48,214,794, 171 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr8:40,519,565–145,066,685, 1,618 genes, copy number 7–12 (broad region; genes not listed).
- chr19:12,763,003–16,066,312, 175 genes, copy number 9–15 (within-gene range 2–15) (broad region; genes not listed).
- chr19:16,074,293–16,077,395, 1 gene, copy number 9: AC008894.3.
- chr19:16,892,951–17,026,815, 1 gene, copy number 9 (within-gene range 5–9): CPAMD8.
- chr19:17,009,189–17,521,288, 38 genes, copy number 9: AC020908.2, HAUS8, AC020908.1, MYO9B, AC020908.3, AC020913.1, AC020913.3, AC020913.2, USE1, OCEL1, NR2F6, AC010646.1, USHBP1, BABAM1, AC010463.1, ANKLE1, ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3, PLVAP, AC010463.2, CCDC194, BST2, BISPR, MVB12A, AC010319.4, AC010319.1, AC010319.3, TMEM221, AC010319.2, AC010319.5, NXNL1, SLC27A1, AC010618.3, PGLS.
- chr19:17,933,015–19,750,127, 96 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:14,371,115–19,900,043, 82 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,193. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
